Somatic mutation profile of tumor specimen MP2PRT-PAUJCZ-TMP1-A (aliquot MP2PRT-PAUJCZ-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUJCZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (954 days).
Specimen MP2PRT-PAUJCZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1596b20c-9945-45b4-acd3-b5e751e362bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJCZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJCZ-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f11a3ad-78e4-4c4a-93f6-56cf821a1d93

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMP19 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 151/464 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.541); catalogued as rs749618891; called by muse, mutect2, varscan2
- MTOR | c.7571A>T p.Q2524L | Missense Mutation (SNP) | VAF 30/383 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63875858; called by muse, mutect2
- TRPC7 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 36/608 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1182478627, COSV61452031; called by muse, mutect2
- IGLV4-69 | c.356_357insCCACCCC p.*120Hfs*? | Frame Shift Ins (INS) | VAF 27/195 reads (14%) | called by mutect2, pindel, varscan2
- WNT2B | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 52/475 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FDFT1 | c.100-24G>A | Intron (SNP) | VAF 147/542 reads (27%) | catalogued as rs1202089353; called by muse, mutect2, varscan2
